Surgical pathology report (de-identified scan), TCGA case TCGA-73-4668, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-73-4668-01A (Primary Tumor).

[page 1 of 4]
Pa
Me
Da
Sex
En
Phy

SURGICAL PATHOLOGY REPORT

SPECIMEN(S):

- A. 4L LEFT DISTAL PARATRACHEAL
- B. 4R RIGHT DISTAL PARATRACHEAL
- C. ADDITIONAL 4R LYMPH NODE
- D. LEVEL 7 SUBCARINAL LYMPH NODE
- E. 2R RIGHT PROXIMAL PARATRACHEAL
- F. LEFT UPPER LOBE
- G. PORTION OF LUNG ATTACHED TO MEDIASTINUM
- H. LEVEL 5 LYMPH NODES
- I. LEVEL 9 LYMPH NODES

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Left upper lobe lung mass

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA, FSB, FSC-lymph nodes 4L, 4R, 4R additional: Negative for tumor.

FSD-7 subcarinal: Fibroadipose tissue negative for tumor; no lymphoid tissue identified.

FSE-2R: Negative for tumor.

FSF-left lung, upper lobe, lobectomy: Bronchial margin is negative for carcinoma, tumor is adenocarcinoma diagnosis called by [REDACTED]

[REDACTED] m.(r).

GROSS DESCRIPTION:

A. 4L LEFT DISTAL PARATRACHEAL

[page 2 of 4]
Received fresh, labeled with matching patient identifiers, are 4 pieces of soft tissue ranging in size from 0.5 x 0.4 x 0.1 cm to 0.2 x 0.2 x 0.1 cm; submitted entirely for frozen section diagnosis in cassette FSA.

B. 4R RIGHT DISTAL PARATRACHEAL

Received fresh, labeled with matching patient identifiers, are 5 pieces of soft tissue ranging from 1 x 0.6 x 0.3 cm to 0.3 x 0.1 x 0.1 cm; submitted entirely for frozen section diagnosis in cassette FSB.

C. 4R RIGHT DISTAL PARATRACHEAL (ADDITIONAL)

Received fresh, labeled with matching patient identifiers, is a piece of soft tissue measuring 0.4 x 0.3 x 0.1 cm; submitted entirely for frozen section diagnosis in cassette FSC.

D. LEVEL 7 LYMPH NODE

Received fresh, labeled with matching patient identifiers, are 3 pieces of soft tissue ranging in size from 0.6 x 0.2 x 0.1 cm to 0.4 x 0.1 x 0.1 cm; submitted entirely for frozen section diagnosis in cassette FSD.

E. 2R RIGHT PROXIMAL PARATRACHEAL

Received fresh, labeled with matching patient identifiers, are 3 pieces of soft tissue each measuring 0.4 x 0.3 x 0.2 cm; submitted entirely for frozen section diagnosis in cassette FSE.

F. LEFT UPPER LOBE

Received fresh, labeled with matching patient identifiers, is a 315-g lobectomy measuring 20 x 9 x 5 cm including entire upper lobe and a 6.7 x 5.6 x 1.9-cm segment of lower lobe (which is adhered to the upper lobe by adhesions). A blue stripe marks the margin to the superior mediastinal pericardial border. A shave is taken of the bronchial margin and submitted for frozen section diagnosis; the bronchi are opened and are smooth and tan in coloration. The pleural surface is focally puckered; it is inked. On sectioning, there is a firm well circumscribed mass, 4.2 x 3.5 x 3 cm. A section is submitted for frozen section diagnosis. The remainder of the parenchyma is unremarkable; tissue is procured. Representative sections are submitted as follows:

FSF1-FSF2: frozen sections

F3: area indicated with a blue stripe

F4: mass and relationship to lower lobe

F5: mass and relationship to pleura/pleural adhesions

F6: mass and bronchi

F7: 1 lymph node

F8: 8 lymph nodes

F9: normal-appearing parenchyma

G. PORTION OF LUNG ATTACHED TO MEDIASTINUM

Received fresh, labeled with matching patient identifiers, is a wedge of lung, 8 x 3.5 x 1.8 cm and weighing 22 g. The surgical margin is 9 cm in length; pleural surface has adhesions and a

[page 3 of 4]
defect, 3.5 cm. On sectioning, no abnormalities are identified. Representative sections of area of adhesions and defect are submitted in cassettes G1-G2.

H. LEVEL 5 LYMPH NODES

Received fresh, labeled with matching patient identifiers, a piece of tan soft tissue admixed with black lymphoid tissue measuring 2.4 x 1.3 x 0.5 cm. Submitted entirely in cassette H1.

I. LEVEL 9 LYMPH NODE

Received fresh, labeled with matching patient identifiers, is an anthracotic lymph node admixed with fat, 1.4 x 1.1 x 0.6 cm. Submitted in cassette I1.

DIAGNOSIS:

A. LYMPH NODE, LEFT DISTAL PARATRACHEAL – 4L, RESECTION:

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).

B. LYMPH NODE, RIGHT DISTAL PARATRACHEAL – 4R, RESECTION:

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).

C. LYMPH NODE, RIGHT DISTAL PARATRACHEAL – 4R, RESECTION:

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).

D. SOFT TISSUE, SUBMITTED AS, "LEVEL 7 LYMPH NODE", RESECTION:

- NO MALIGNANCY IDENTIFIED.

E. LYMPH NODE, RIGHT PROXIMAL PARATRACHEAL – 2R, RESECTION:

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).

F. LUNG, LEFT UPPER LOBE, LOBECTOMY:

- ADENOCARCINOMA WITH MICROPAPILLARY FEATURES, MODERATELY DIFFERENTIATED.
- 4.2 CM IN GREATEST DIMENSION.
- 3.5 X 3.0 CM IN ADDITIONAL DIMENSIONS.
- NO PLEURAL INVASION IDENTIFIED.
- THE BRONCHIAL MARGINS NEGATIVE FOR TUMOR.
- NO ANGIOLYMPHATIC INVASION IDENTIFIED.
- EMPHYSEMATOUS CHANGES.
- METASTATIC CARCINOMA TO ONE OF ELEVEN PERIBRONCHIAL LYMPH NODES (1/11), WITH EXTRANODAL EXTENSION.

G. LUNG, ATTACHED TO MEDIASTINUM, RESECTION:

- EMPHYSEMATOUS CHANGES.
- NO MALIGNANCY IDENTIFIED IN ONE INTRAPULMONARY LYMPH NODE (0/1).
-

[page 4 of 4]
H. LYMPH NODE, LEVEL 5, RESECTION:

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).

I. LYMPH NODE, LEVEL 9, RESECTION:

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).

SYNOPTIC REPORT - LUNG

Specimens Involved

Specimens: F: LEFT UPPER LOBE

Surgical Procedure: Lobectomy

Laterality: Left

Tumor Site: Upper lobe

Tumor Location: Peripheral

Tumor Size: Greatest diameter: 4.2cm

Additional dimensions: 3.5cm x 3cm

WHO CLASSIFICATION

Adenocarcinoma

Histologic Grade: G2: Moderately differentiated

Angiolymphatic Invasion: Absent

Bronchial Margins: Bronchial margins uninvolved

Visceral Pleural Involvement: Absent

Satellite Tumor(s): Absent

Lymph Node Involvement: N1: Ipsilateral Hilar and/or Peribronchial (levels 10-14)
Positive 1 / 12

N2: Ipsilateral Mediastinal and/or Subcarinal (Levels 1-9)
Negative 0 / 3

N3: Contralateral Mediastinal/Hilar, Scalene or Supraclavicular
Negative 0 / 3

Non-Neoplastic Lung: Emphysematous changes

Additional Pathologic Findings: None identified

Pathological Staging (pTNM): pT 2 N 1 M X

Source: NCI Genomic Data Commons file 64b09884-3eef-43f7-b11d-2ffcf56fa49e (TCGA-73-4668.9177E909-F92C-4B50-A256-A4F840A05140.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).